CPTAC case C3N-01017 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1e7c8c8e-4c3c-429b-b34e-34677f07d1a4

Demographics
Sex at birth: male; Race: asian; Year of birth: 1960; Vital status: Alive; Country of birth: Vietnam.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Age at diagnosis: 56.8 years (20,756 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 459 days (1.3 years); Progression or recurrence: no; Days to last follow up: 459 days (1.3 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.5 cm (a second GDC size field records 3 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 8; Margin status: Uninvolved.

Follow-up (1 entry)
- Days to follow up: 459 days (1.3 years); Disease response: Tumor Free; Karnofsky performance status: 70; ECOG performance status: 3.

Other clinical attributes
- Weight: 58 kg; Height: 170 cm; BMI: 20.07.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 5; Cigarettes per day: 5; Tobacco smoking onset year: 1996; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 26.

Biospecimens (14 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Samples C3N-01017-01, C3N-01017-02, C3N-01017-03 (3 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 250 mg.
- Sample C3N-01017-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 6 days; Initial weight: 250 mg; Time between clamping and freezing: 24 minutes; Time between excision and freezing: 4 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01017-24: Section location: Lung, not otherwise specified; Percent tumor nuclei: 70; Percent necrosis: 15.
- Sample C3N-01017-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 6 days; Initial weight: 200 mg; Time between clamping and freezing: 25 minutes; Time between excision and freezing: 5 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-01017-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 200 mg.
- Samples C3N-01017-31, C3N-01017-32, C3N-01017-72, C3N-01017-73, C3N-01017-74, C3N-01017-75, C3N-01017-76 (7 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-01017-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 6 days; Method of sample procurement: Blood Draw.
